TCGA case TCGA-BG-A3PP — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9f92080f-f6e0-42db-a02b-b3069664f6d0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 82 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 82.8 years (30,227 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; FIGO stage: Stage II; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 681 days (1.9 years).
   Pathology details: Consistent pathology review: Yes.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes tested: 3.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 74 days; Days to treatment end: 186 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 238 days; Days to treatment end: 253 days; Treatment dose: 20 Gy; Treatment outcome: Complete Response; Number of fractions: 11; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS), site: Vagina, NOS. Age at diagnosis: 84.6 years (30,892 days); Days to diagnosis: 665 days (1.8 years); Prior treatment: Yes.

Follow-up (4 entries)
- Days to follow up: 207 days; Disease response: Tumor Free.
- Day 665 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Vagina, NOS; Days to recurrence: 665 days (1.8 years).
- Days to follow up: 681 days (1.9 years); Disease response: With Tumor.
- Peritoneal washing results: Positive; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BG-A3PP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 320 mg.
  Slide TCGA-BG-A3PP-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 70; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BG-A3PP-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BG-A3PP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-BG-A3PP-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 190 mg.
  Slide TCGA-BG-A3PP-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Serous endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: Minimally Invasive; Lymph nodes pelvic pos by he: 0.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Progressive Disease; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 681 days; disease-specific survival: no event (censored), 681 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 665 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BG-A3PP-01A-11D-A227-01): tumor purity 0.59, ploidy 3.55, whole-genome doublings 1.
